Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A5VH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A5VH-01A (Primary Tumor).

[page 1 of 3]
Result History

Result Date and Time

Status

Final result

Priority

Routine

Report Assistance Message

ICD-0-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
053.9
JND 4/4/13

Component Results

Surgical Pathology:

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

UTERUS, CERVIX, BIOPSIES OF MASS:

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED

Comment: The findings were discussed with

Staff Pathologist

Pertinent Clinical Information

Pertinent History/Operative Findings: -year-old G2 P2 with cervical mass/vaginal mass, obliterates vagina.

Gross Description

Specimen Material: Cervical mass biopsy.

The case is received in one part labeled with the patient's name. medical record number and given accession number and it is accompanied by a requisition form labeled with the same name and same accession number.

[page 2 of 3]
The specimen is received in formalin labeled as "CERVICAL MASS BIOPSY" and consists of two tan-pink to tan-white pieces of tissue, 0.5 x 0.4 x 0.2 cm each. The resection surface of both portions are inked blue. The specimen is submitted entirely in one cassette.

Pathology Resident
Microscopic Description
Cervical mass biopsies have moderately differentiated squamous cell carcinoma with an extensive ulceration and necrosis. Clouds of bacteria are seen.
The staff pathologist listed below reviewed this case.

Staff Pathologist

Result History

Result Date and Time

Status

In process

Priority

Routine

Report Assistance Message

Results Routing Details for Order:

Outcome:	Result not sent
Routing Scheme Used:	Routing using only CC list
Routing Scheme Line:	Default
Resulting User:	
Routing Instant:	
Comments:	Routing Scheme configured to have no recipients
Current Status:	Routing Complete
Status History:	Result contact created Routing started Routing Complete
Outcome:	Result not sent
Resulting User:	Lab In Interface
Routing Instant:	
Comments:	An message was not sent because no results were filed
Current Status:	Routing Complete
Status History:	Result contact created Routing Complete

Order Transmittal Details for Order:

There is no tracking information for this order. Either the order has not gone through order transmittal or the tracking data has been purged from the system due to age.

[page 3 of 3]
Performance Data For

Source: NCI Genomic Data Commons file 43d27953-06aa-4d96-be87-919b8e9301b9 (TCGA-JW-A5VH.D5B62718-1D34-45F7-8DDB-B106AC85B102.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).